MMRF case MMRF_1922 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3d474556-8c72-4782-8c9f-97b68563b259

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.5 years (21,374 days); ISS stage: III; Days to last known disease status: 1,036 days (2.8 years); Days to last follow up: 1,036 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 169 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 271 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 236 days; Days to treatment end: 236 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 265 days; Days to treatment end: 265 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1210 mg/dL; Immunoglobulin G 20.9 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 6.06 µg/mL; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 1.88 mmol/L; Albumin 27 g/L; Total Protein 5.7 g/dL; Glucose 4.95 mmol/L; C-Reactive Protein 3.8 mg/dL.
- Day 89: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 126 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.55 g/L; Hemoglobin 8 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.45 mmol/L.
- Day 180: M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.7 mg/dL; Immunoglobulin G 6.09 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.8 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.9 mmol/L.
- Day 335 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.39 mg/dL; Immunoglobulin G 6.92 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.9 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.06 mmol/L.
- Day 405 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.24 mg/dL; Immunoglobulin G 7.16 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 1.63 g/L; Hemoglobin 9.18 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.17 mmol/L.
- Day 536 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.74 mg/dL; Immunoglobulin G 8.58 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 2.26 g/L; Hemoglobin 9.36 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 84 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 4.84 mmol/L.
- Day 630 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.13 mg/dL; Hemoglobin 9.11 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 4.57 mmol/L.
- Day 691 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.09 mg/dL; Hemoglobin 8.99 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 76 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 6.16 mmol/L.
- Day 775 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.65 mg/dL; Hemoglobin 9.24 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 81 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 6.38 mmol/L.
- Day 873 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.05 mg/dL; Hemoglobin 9.11 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 5.56 mmol/L.
- Day 979 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.47 mg/dL; Lactate Dehydrogenase 6.7 µkat/L; Hemoglobin 9.67 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 5.94 mmol/L.
- Day 1,036 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.9 mg/dL; Hemoglobin 9.05 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 70 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 8.7 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -13: Weight: 104 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1922_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1922_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
